Somatic mutation profile of tumor specimen C3L-03985-03 (aliquot CPT0254880007) from CPTAC case C3L-03985, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 67.7 years (24,731 days).
Specimen C3L-03985-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7167754-8abd-4e9e-a6f3-74d523a39143.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03985-31 (Blood Derived Normal), aliquot CPT0255020002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8f599eb-1015-4f27-8ebb-59ca0394d31a

The open-access MAF lists 1,797 somatic variants for this specimen: 1,227 protein-altering or splice-affecting, 336 silent, 234 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,061, Silent 336, Intron 92, Nonsense Mutation 84, RNA 49, 3'UTR 33, 5'UTR 30, Frame Shift Del 30, Splice Site 27, 5'Flank 24, Splice Region 14, Frame Shift Ins 7.

Variants (750 of 1,797; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.783-1G>T p.X261_splice | Splice Site (SNP) | VAF 189/602 reads (31%) | hotspot (GDC flag); catalogued as rs1555525367, CS137625, COSV52668714, COSV52729930, COSV53769335; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 38/238 reads (16%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- AAAS | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 31/606 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145235560; called by muse, mutect2
- ABCB1 | c.2917G>T p.D973Y | Missense Mutation (SNP) | VAF 53/370 reads (14%) | SIFT tolerated (1); PolyPhen probably damaging (0.923); catalogued as rs748995428; called by muse, mutect2, varscan2
- ABT1 | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 26/167 reads (16%) | catalogued as COSV51290869; called by muse, mutect2
- ADAMTS14 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs756453410, COSV64600199; called by muse, mutect2, varscan2
- ADAMTS16 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 58/370 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.096); catalogued as COSV56996112; called by muse, mutect2, varscan2
- ADAMTS16 | c.2366G>A p.R789H | Missense Mutation (SNP) | VAF 203/522 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs754087133; called by muse, mutect2, varscan2
- ADAMTS3 | c.3158G>T p.R1053L | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.646); catalogued as rs370314161; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1621G>A p.G541R | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477010817; called by muse, mutect2
- ADAMTSL2 | c.540C>A p.C180* | Nonsense Mutation (SNP) | VAF 190/474 reads (40%) | catalogued as COSV63203188, COSV63204677; called by muse, mutect2, varscan2
- ADAMTSL3 | c.309G>T p.L103F | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99717603; called by muse, mutect2, varscan2
- ADARB2 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 57/323 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV67219384; called by muse, mutect2, varscan2
- ADCY2 | c.1976C>A p.S659Y | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.067); catalogued as COSV104404738; called by muse, mutect2, varscan2
- ADGRB3 | c.1400G>T p.C467F | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755657156; called by muse, mutect2, varscan2
- AGMO | c.1150G>T p.D384Y | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100694502; called by muse, mutect2, varscan2
- AHNAK2 | c.11038G>T p.D3680Y | Missense Mutation (SNP) | VAF 89/564 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs762879519; called by muse, mutect2, varscan2
- AJAP1 | c.474C>A p.H158Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs1238367819; called by muse, mutect2, varscan2
- ALKBH8 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.068); catalogued as rs770292890; called by muse, mutect2, varscan2
- ANKRD30B | c.209A>G p.D70G | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs745517825; called by muse, mutect2, varscan2
- ANKRD30B | c.3803G>T p.R1268L | Missense Mutation (SNP) | VAF 54/301 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100271436, COSV57703864; called by muse, mutect2, varscan2
- ANKRD36 | c.1837G>A p.V613M | Missense Mutation (SNP) | VAF 86/536 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1293337404, COSV70741446; called by muse, mutect2, varscan2
- APOB | c.3676G>T p.V1226L | Missense Mutation (SNP) | VAF 40/288 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs138681343, COSV99266086; called by muse, mutect2, varscan2
- APOC3 | c.280A>T p.T94S | Missense Mutation (SNP) | VAF 109/546 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as CM870005; called by muse, mutect2, varscan2
- ARHGEF4 | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 37/242 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.238); catalogued as rs759020167, COSV58125752; called by muse, mutect2, varscan2
- ARMCX3 | c.846G>T p.R282S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV57871082; called by muse, mutect2, varscan2
- ARMH4 | c.2161G>T p.G721W | Missense Mutation (SNP) | VAF 41/343 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758438763; called by muse, mutect2, varscan2
- ARPP21 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs374241256; called by muse, mutect2, varscan2
- ARVCF | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 52/451 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs771976158; called by muse, mutect2, varscan2
- ASCL1 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 124/380 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57151428; called by muse, mutect2, varscan2
- ATAD2 | c.406A>G p.R136G | Missense Mutation (SNP) | VAF 79/154 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.057); catalogued as rs1307130934; called by muse, mutect2, varscan2
- ATG2A | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 33/230 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs758839871; called by muse, mutect2, varscan2
- ATP12A | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.255); catalogued as rs1434705896; called by muse, mutect2
- AZGP1 | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 128/280 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs146017934; called by muse, mutect2, varscan2
- BICDL1 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as COSV99985771; called by muse, mutect2, varscan2
- BMP7 | c.408C>A p.F136L | Missense Mutation (SNP) | VAF 40/650 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); catalogued as COSV101215931; called by muse, mutect2
- BRCA1 | c.4997A>T p.Y1666F | Missense Mutation (SNP) | VAF 108/424 reads (25%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as CM087390; called by muse, mutect2, varscan2
- BRF2 | c.824G>T p.R275L | Missense Mutation (SNP) | VAF 65/326 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs774849654; called by muse, mutect2, varscan2
- C1QTNF3 | c.284G>C p.R95P | Missense Mutation (SNP) | VAF 88/195 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV99180737; called by muse, mutect2, varscan2
- C2CD3 | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 25/360 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV100487378; called by muse, mutect2
- C4B | c.2513G>T p.R838L | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1233787148; called by mutect2, varscan2
- C8B | c.1273G>T p.V425F | Missense Mutation (SNP) | VAF 86/469 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs769416892, COSV64776877; called by muse, mutect2, varscan2
- CA8 | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs767070057; called by muse, mutect2, varscan2
- CACNA1E | c.2285G>T p.R762L | Missense Mutation (SNP) | VAF 45/397 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.184); catalogued as COSV100701577, COSV62391937, COSV62405729; called by muse, mutect2, varscan2
- CACNA1G | c.6545G>T p.R2182L | Missense Mutation (SNP) | VAF 77/338 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs1233837845; called by muse, mutect2, varscan2
- CACNA1I | c.2761G>T p.G921C | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV60817864; called by muse, mutect2, varscan2
- CACNB2 | c.343G>T p.V115F (on ENST00000324631 / NM_201596.3; = p.V60F on NM_000724.4) | Missense Mutation (SNP) | VAF 77/486 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747480172; called by muse, mutect2, varscan2
- CARMIL2 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 85/185 reads (46%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs781351613; called by muse, mutect2, varscan2
- CBLN1 | c.344A>G p.N115S | Missense Mutation (SNP) | VAF 76/207 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV54655470; called by muse, mutect2, varscan2
- CBY2 | c.249G>T p.R83S | Missense Mutation (SNP) | VAF 86/209 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.442); catalogued as COSV100137668; called by muse, mutect2, varscan2
- CCDC168 | c.3494T>A p.I1165N | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.38); catalogued as rs774350510, COSV70555637; called by muse, mutect2, varscan2
- CDHR3 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 44/327 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as rs372834692; called by muse, mutect2, varscan2
- CFAP221 | c.1411-1G>T p.X471_splice | Splice Site (SNP) | VAF 30/121 reads (25%) | catalogued as COSV99732120; called by muse, mutect2, varscan2
- CFAP47 | c.4388C>A p.S1463Y | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.801); catalogued as COSV57974405; called by muse, mutect2, varscan2
- CFH | c.2195C>A p.T732K | Missense Mutation (SNP) | VAF 75/394 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as CM124965, COSV66410451; called by muse, mutect2, varscan2
- CHN1 | c.288G>T p.R96S | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs529935785; called by muse, mutect2, varscan2
- CLVS1 | c.212C>A p.T71K | Missense Mutation (SNP) | VAF 63/428 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.356); catalogued as COSV57975777; called by muse, mutect2, varscan2
- CNTN5 | c.2665G>T p.V889L | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV54296251; called by muse, mutect2, varscan2
- CNTNAP2 | c.1958A>G p.Y653C | Missense Mutation (SNP) | VAF 97/465 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV62212203; called by muse, mutect2, varscan2
- CNTNAP2 | c.2840T>G p.L947R | Missense Mutation (SNP) | VAF 98/463 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100673817; called by muse, mutect2, varscan2
- CNTNAP5 | c.1939C>A p.P647T | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs774766192, COSV70517441; called by muse, mutect2, varscan2
- COL11A1 | c.2722G>A p.G908S | Missense Mutation (SNP) | VAF 75/450 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs758953085; called by muse, mutect2, varscan2
- COL3A1 | c.574G>T p.G192C | Missense Mutation (SNP) | VAF 85/316 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1276176086, COSV100483513; called by muse, mutect2, varscan2
- COL5A1 | c.5280C>A p.Y1760* | Nonsense Mutation (SNP) | VAF 167/444 reads (38%) | catalogued as COSV65668531; called by muse, mutect2, varscan2
- COL9A1 | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 53/279 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV61834314; called by muse, mutect2, varscan2
- COLEC10 | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV60523232; called by muse, mutect2, varscan2
- COPB1 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377571611; called by muse, mutect2, varscan2
- CPT1A | c.1807G>T p.E603* | Nonsense Mutation (SNP) | VAF 130/477 reads (27%) | catalogued as COSV99681474; called by muse, mutect2, varscan2
- CRB1 | c.1789A>G p.T597A | Missense Mutation (SNP) | VAF 194/633 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs1276695150; called by muse, mutect2, varscan2
- CRHR1 | c.97C>A p.L33M | Missense Mutation (SNP) | VAF 21/287 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as COSV53287914; called by muse, mutect2
- CSH2 | c.144G>T p.Q48H | Missense Mutation (SNP) | VAF 96/912 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.769); catalogued as COSV100400219; called by muse, mutect2
- CSMD1 | c.8099G>A p.R2700K (on ENST00000520002; = p.R2699K on NM_033225.6) | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as rs944633877; called by muse, mutect2
- CSMD1 | c.1494C>A p.S498R (on ENST00000520002; = p.S497R on NM_033225.6) | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); catalogued as rs368753576; called by muse, mutect2, varscan2
- CSMD3 | c.1184G>T p.R395L | Missense Mutation (SNP) | VAF 83/556 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.018); catalogued as COSV52105622, COSV52155991; called by muse, mutect2, varscan2
- CTAGE1 | c.2164G>T p.V722F | Missense Mutation (SNP) | VAF 95/213 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.751); catalogued as COSV66943363; called by muse, mutect2, varscan2
- CTLA4 | c.625C>A p.P209T | Missense Mutation (SNP) | VAF 45/354 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55593127; called by muse, mutect2, varscan2
- CYB5R1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 107/291 reads (37%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as rs1332561845; called by muse, mutect2, varscan2
- CYP11B1 | c.396-1G>C p.X132_splice | Splice Site (SNP) | VAF 283/715 reads (40%) | catalogued as CS1515481; called by muse, mutect2, varscan2
- CYP19A1 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 67/463 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV53063044; called by muse, mutect2, varscan2
- CYP3A43 | c.691C>A p.P231T | Missense Mutation (SNP) | VAF 116/287 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as CM1513167; called by muse, mutect2, varscan2
- D2HGDH | c.697G>C p.G233R | Missense Mutation (SNP) | VAF 59/440 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as CM101387; called by muse, mutect2, varscan2
- DEFA5 | c.260G>T p.R87L | Missense Mutation (SNP) | VAF 59/348 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as rs373926117; called by muse, mutect2, varscan2
- DENND2A | c.2009G>T p.R670L | Missense Mutation (SNP) | VAF 59/284 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs562738531, COSV52053144; called by muse, mutect2, varscan2
- DENND5B | c.640G>T p.A214S | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as rs776213713; called by muse, mutect2, varscan2
- DISP1 | c.852G>A p.W284* | Nonsense Mutation (SNP) | VAF 30/426 reads (7%) | catalogued as rs79910153, COSV52654927; called by muse, mutect2
- DLGAP3 | c.740G>T p.R247L | Missense Mutation (SNP) | VAF 51/270 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs1240043767, COSV52393120; called by muse, mutect2, varscan2
- DMBT1 | c.2377G>C p.G793R | Missense Mutation (SNP) | VAF 300/921 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV57544071; called by muse, mutect2, varscan2
- DNAAF5 | c.667G>T p.V223F | Missense Mutation (SNP) | VAF 135/458 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs755873855; called by muse, mutect2, varscan2
- DNAH3 | c.4735G>T p.A1579S | Missense Mutation (SNP) | VAF 75/261 reads (29%) | SIFT tolerated (0.8); PolyPhen benign (0.401); catalogued as COSV54504157, COSV54553447; called by muse, mutect2, varscan2
- DNAH5 | c.5929G>T p.A1977S | Missense Mutation (SNP) | VAF 177/410 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.785); catalogued as rs143894811; called by muse, mutect2, varscan2
- DNAI2 | c.1130C>A p.P377Q | Missense Mutation (SNP) | VAF 132/405 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs199726930; called by muse, mutect2, varscan2
- DPP10 | c.1528G>T p.A510S | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100058551; called by muse, mutect2, varscan2
- DSG2 | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 55/274 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); catalogued as COSV99853491; called by muse, mutect2, varscan2
- DST | c.13808A>T p.D4603V (on ENST00000361203 / NM_001374722.1; = p.D2191V on NM_015548.5) | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs1207713253; called by muse, varscan2
- DYSF | c.5078G>T p.R1693L | Missense Mutation (SNP) | VAF 88/449 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as CM053206, COSV50280819; called by muse, mutect2, varscan2
- EFNA5 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 72/215 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as COSV60959279; called by muse, mutect2, varscan2
- ELF3 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 54/174 reads (31%) | catalogued as rs1258691938, COSV62837353; called by muse, mutect2, varscan2
- EXOG | c.7A>G p.I3V | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs916982789; called by muse, mutect2, varscan2
- EYS | c.2542C>A p.Q848K | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as COSV101012386; called by muse, varscan2
- F13A1 | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 107/511 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913071, CM043488, CM990522, COSV53558106; called by muse, mutect2, varscan2
- FAM135B | c.1933A>T p.S645C | Missense Mutation (SNP) | VAF 43/257 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV52714592; called by muse, mutect2, varscan2
- FAM47B | c.489G>C p.W163C | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV61454297; called by muse, mutect2, varscan2
- FAM83B | c.179A>T p.E60V | Missense Mutation (SNP) | VAF 26/361 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1373167891; called by muse, mutect2
- FAT3 | c.6082A>T p.I2028L | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99970592; called by muse, mutect2, varscan2
- FLG2 | c.6811C>T p.H2271Y | Missense Mutation (SNP) | VAF 181/759 reads (24%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.613); catalogued as rs773892932; called by muse, mutect2, varscan2
- FOXD4L6 | c.1075C>A p.H359N | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); catalogued as rs1403564825; called by mutect2, varscan2
- FOXP2 | c.2125C>A p.P709T | Missense Mutation (SNP) | VAF 73/493 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1236343176, COSV63482706; called by muse, mutect2, varscan2
- FPR1 | c.422T>A p.L141Q | Missense Mutation (SNP) | VAF 53/294 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV59054120; called by muse, mutect2, varscan2
- FREM2 | c.5090G>T p.R1697I | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV99749594; called by muse, mutect2, varscan2
- FSCB | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as rs554125229, COSV61216671; called by muse, mutect2, varscan2
- FTMT | c.651del p.M218Wfs*35 | Frame Shift Del (DEL) | VAF 86/272 reads (32%) | catalogued as COSV58419617; called by mutect2, pindel, varscan2
- GABRB2 | c.678A>G p.T226= | Splice Region (SNP) | VAF 27/114 reads (24%) | catalogued as COSV50939776; called by muse, mutect2
- GABRR1 | c.872C>A p.P291H | Missense Mutation (SNP) | VAF 42/211 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65620091; called by muse, mutect2, varscan2
- GAD2 | c.685G>T p.G229C | Missense Mutation (SNP) | VAF 54/384 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1276993275, COSV52163477; called by mutect2, varscan2
- GADL1 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.266); catalogued as COSV56978948, COSV56978993; called by muse, mutect2, varscan2
- GALNT6 | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 38/382 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV62541702; called by muse, mutect2
- GDF10 | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.38); catalogued as rs781783079; called by muse, mutect2
- GLI1 | c.1468A>T p.T490S | Missense Mutation (SNP) | VAF 311/700 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.076); catalogued as COSV99954735; called by muse, mutect2, varscan2
- GLI3 | c.3098C>A p.P1033Q | Missense Mutation (SNP) | VAF 53/332 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as rs376956433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLYAT | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53539778, COSV99557622; called by muse, mutect2, varscan2
- GNAS | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 84/1384 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs761439049; called by muse, mutect2
- GOT1 | c.861G>T p.Q287H | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV100981775; called by muse, mutect2, varscan2
- GPRC6A | c.1426G>T p.V476F | Missense Mutation (SNP) | VAF 94/395 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.938); catalogued as COSV59953161; called by muse, mutect2, varscan2
- GPX5 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 79/423 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as COSV69079415; called by muse, mutect2, varscan2
- GRIFIN | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 31/477 reads (6%) | SIFT tolerated (0.94); PolyPhen benign (0.038); catalogued as rs767361129; called by muse, mutect2
- GRM1 | c.240G>T p.E80D | Missense Mutation (SNP) | VAF 89/360 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99264092; called by muse, mutect2, varscan2
- GSTA2 | c.171G>T p.M57I | Missense Mutation (SNP) | VAF 47/271 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); catalogued as rs183168307; called by muse, mutect2, varscan2
- HCRTR2 | c.117C>A p.F39L | Missense Mutation (SNP) | VAF 249/724 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV63799866; called by muse, mutect2, varscan2
- HECW1 | c.2737G>T p.G913* | Nonsense Mutation (SNP) | VAF 40/239 reads (17%) | catalogued as COSV67829457; called by muse, mutect2, varscan2
- HEPH | c.593G>T p.G198V (on ENST00000343002; = p.G252V on NM_138737.5) | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57973728; called by muse, mutect2, varscan2
- HMCN1 | c.9614G>A p.G3205E | Missense Mutation (SNP) | VAF 42/506 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV54891505; called by muse, mutect2
- HNRNPUL2 | c.593G>T p.R198L | Missense Mutation (SNP) | VAF 97/441 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.24); catalogued as COSV53664998; called by muse, mutect2, varscan2
- HOXA11 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 75/305 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.042); catalogued as rs766858171; called by muse, mutect2, varscan2
- HOXD12 | c.608G>T p.R203L | Missense Mutation (SNP) | VAF 94/271 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1395222154, COSV66832726, COSV66832882; called by muse, mutect2, varscan2
- HRNR | c.2552C>A p.S851* | Nonsense Mutation (SNP) | VAF 157/533 reads (29%) | catalogued as rs774716470; called by muse, mutect2, varscan2
- HROB | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 81/302 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs563980398, COSV55368847; called by muse, mutect2, varscan2
- IFT172 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.624); catalogued as rs1038040281, COSV53134002; called by muse, mutect2, varscan2
- IGHV1-24 | c.211G>C p.D71H | Missense Mutation (SNP) | VAF 118/606 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs570502677; called by muse, mutect2, varscan2
- IGHV3-64 | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 124/530 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.404); catalogued as rs138428007; called by muse, mutect2, varscan2
- IL7R | c.297C>A p.F99L | Missense Mutation (SNP) | VAF 43/404 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV57407414, COSV57413041; called by muse, mutect2, varscan2
- IMPDH1 | c.709A>T p.K237* (on ENST00000470772 / NM_001142573.2; = p.K323* on NM_000883.4) | Nonsense Mutation (SNP) | VAF 23/146 reads (16%) | catalogued as CM053930; called by muse, mutect2, varscan2
- IMPDH2 | c.1438C>G p.R480G | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV58247168; called by muse, mutect2, varscan2
- ISM1 | c.580dup p.R194Kfs*14 | Frame Shift Ins (INS) | VAF 94/446 reads (21%) | catalogued as COSV52607088; called by pindel, varscan2
- JCAD | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 152/539 reads (28%) | catalogued as COSV100947962; called by muse, mutect2, varscan2
- KBTBD6 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 116/297 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778381099; called by muse, mutect2, varscan2
- KCNH5 | c.886G>T p.D296Y | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59767610; called by muse, mutect2, varscan2
- KEAP1 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 45/427 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.94); catalogued as COSV50272179; called by muse, mutect2, varscan2
- KIF21A | c.3598G>T p.E1200* (on ENST00000361418 / NM_001378440.1; = p.E1187* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 220/595 reads (37%) | catalogued as COSV100735431; called by muse, mutect2, varscan2
- KIF4B | c.1149G>T p.E383D | Missense Mutation (SNP) | VAF 185/414 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV70529977; called by muse, mutect2, varscan2
- KLC1 | c.425A>T p.E142V | Missense Mutation (SNP) | VAF 88/400 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs760394428; called by muse, mutect2, varscan2
- KLHL1 | c.746A>T p.K249M | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100917425; called by muse, mutect2, varscan2
- KLHL17 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 55/286 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs963904505; called by muse, mutect2, varscan2
- KLHL6 | c.1781G>T p.R594L | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.289); catalogued as COSV58067455; called by muse, mutect2
- KLHL6 | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.103); catalogued as COSV99050088; called by muse, mutect2, varscan2
- KLK13 | c.508+1G>T p.X170_splice | Splice Site (SNP) | VAF 21/109 reads (19%) | catalogued as rs867561798; called by muse, mutect2, varscan2
- KLK15 | c.91C>T p.H31Y | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV56828614; called by muse, mutect2, varscan2
- KRTAP10-8 | c.76C>T p.H26Y | Missense Mutation (SNP) | VAF 89/265 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782736729; called by muse, mutect2, varscan2
- KRTAP4-11 | c.440C>G p.P147R | Missense Mutation (SNP) | VAF 123/645 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV66949333; called by muse, mutect2, varscan2
- LAMA1 | c.5142G>T p.L1714F | Missense Mutation (SNP) | VAF 74/346 reads (21%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.621); catalogued as rs1289623311, COSV67532219; called by muse, mutect2, varscan2
- LAMA5 | c.7080G>A p.W2360* | Nonsense Mutation (SNP) | VAF 157/364 reads (43%) | catalogued as rs1447340907; called by muse, mutect2, varscan2
- LIM2 | c.222C>A p.C74* (on ENST00000596399 / NM_001161748.2; = p.C116* on NM_030657.4) | Nonsense Mutation (SNP) | VAF 91/402 reads (23%) | catalogued as rs200121972; called by muse, mutect2, varscan2
- LRP1B | c.2920G>T p.V974L | Missense Mutation (SNP) | VAF 25/244 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs563524207; called by muse, mutect2, varscan2
- LRRC38 | c.846C>A p.N282K | Missense Mutation (SNP) | VAF 47/261 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.115); catalogued as rs1292996711; called by muse, mutect2, varscan2
- LRRTM1 | c.225C>G p.N75K | Missense Mutation (SNP) | VAF 77/240 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV54438290; called by muse, mutect2, varscan2
- LTN1 | c.4609G>A p.D1537N | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs1297588764; called by muse, mutect2, varscan2
- LYN | c.384-1G>T p.X128_splice | Splice Site (SNP) | VAF 48/281 reads (17%) | catalogued as COSV70206350; called by muse, mutect2, varscan2
- MAGEA10 | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 75/186 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as COSV54882887; called by muse, mutect2, varscan2
- MAGEL2 | c.2131G>T p.A711S | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.023); catalogued as COSV58567750; called by muse, mutect2, varscan2
- MAP2 | c.1434G>T p.E478D | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.761); catalogued as COSV52313674; called by muse, mutect2, varscan2
- MAP3K3 | c.1259A>G p.Q420R | Missense Mutation (SNP) | VAF 75/295 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1281681903; called by muse, mutect2, varscan2
- MAPK9 | c.807C>G p.I269M | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV58127227; called by muse, mutect2, varscan2
- MARK1 | c.1868G>T p.R623L | Missense Mutation (SNP) | VAF 98/633 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV100857096, COSV65072006; called by muse, mutect2, varscan2
- MATR3 | c.1885G>C p.E629Q | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as COSV100735318; called by muse, mutect2
- MBTPS2 | c.306G>T p.L102F | Missense Mutation (SNP) | VAF 132/285 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.091); catalogued as COSV100810774; called by muse, mutect2, varscan2
- METTL21C | c.457C>A p.L153I | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.04); catalogued as rs552658471; called by muse, mutect2, varscan2
- METTL24 | c.997C>A p.H333N | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as COSV58824885; called by muse, mutect2, varscan2
- METTL8 | c.145G>T p.D49Y | Missense Mutation (SNP) | VAF 58/278 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs545647826, COSV64549204; called by muse, mutect2, varscan2
- MGAT3 | c.691G>C p.V231L | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.1); catalogued as rs765400998; called by muse, mutect2, varscan2
- MIEF2 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as rs931096070; called by muse, mutect2
- MLIP | c.655C>G p.P219A | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99228715, COSV99230100; called by muse, mutect2, varscan2
- MMD2 | c.691A>G p.R231G (on ENST00000404774 / NM_001100600.2; = p.R207G on NM_198403.4) | Missense Mutation (SNP) | VAF 186/713 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as COSV101286977; called by muse, mutect2, varscan2
- MORN1 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1167105621; called by muse, mutect2
- MPDZ | c.5308G>A p.D1770N | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1309445877, COSV59922197; called by muse, mutect2, varscan2
- MPPED2 | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63899463; called by muse, mutect2, varscan2
- MRTFA | c.1835C>T p.P612L | Missense Mutation (SNP) | VAF 42/237 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.288); catalogued as rs370416906, COSV100844494; called by muse, mutect2, varscan2
- MSLN | c.746G>C p.R249P | Missense Mutation (SNP) | VAF 75/274 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.18); catalogued as COSV99558483; called by muse, mutect2, varscan2
- MSTN | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 37/349 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs965957357; called by muse, mutect2, varscan2
- MTUS2 | c.2281C>G p.R761G | Missense Mutation (SNP) | VAF 171/445 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70922069, COSV70923802; called by muse, mutect2, varscan2
- MUC5AC | c.1431G>T p.R477S | Missense Mutation (SNP) | VAF 114/396 reads (29%) | SIFT deleterious (0.01); catalogued as rs1302298442; called by muse, mutect2, varscan2
- MXRA5 | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs745871213, COSV54224205; called by muse, mutect2, varscan2
- MYBPC2 | c.1721C>T p.P574L | Missense Mutation (SNP) | VAF 58/217 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63100386; called by muse, mutect2, varscan2
- MYH2 | c.3542G>A p.R1181H | Missense Mutation (SNP) | VAF 242/660 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs773196254, COSV55446689; called by muse, mutect2, varscan2
- MYH6 | c.2725C>A p.Q909K | Missense Mutation (SNP) | VAF 212/652 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.418); catalogued as rs1566510145; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAV3 | c.1577G>A p.G526D | Missense Mutation (SNP) | VAF 168/357 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs760821087; called by muse, mutect2, varscan2
- NCKAP5 | c.3299C>A p.P1100H | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.091); catalogued as rs752711460, COSV58472221; called by muse, mutect2, varscan2
- NEB | c.4612G>A p.A1538T | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.358); catalogued as rs781263453, COSV51363647; called by muse, mutect2, varscan2
- NEK8 | c.1675G>T p.D559Y | Missense Mutation (SNP) | VAF 147/430 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.188); catalogued as rs992428098; called by muse, mutect2, varscan2
- NELL1 | c.1528G>T p.G510W | Missense Mutation (SNP) | VAF 92/242 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54296197; called by muse, mutect2, varscan2
- NEUROD1 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs770063497; called by muse, mutect2, varscan2
- NLRP3 | c.414C>G p.Y138* | Nonsense Mutation (SNP) | VAF 66/469 reads (14%) | catalogued as COSV104412132; called by muse, mutect2, varscan2
- NLRP5 | c.3227C>A p.A1076D | Missense Mutation (SNP) | VAF 46/261 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.086); catalogued as rs749480325; called by muse, mutect2, varscan2
- NLRP8 | c.2381+1G>C p.X794_splice | Splice Site (SNP) | VAF 17/79 reads (22%) | catalogued as COSV52592349; called by muse, mutect2, varscan2
- NOX5 | c.1526G>T p.R509L | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52992823; called by muse, mutect2, varscan2
- NPAS3 | c.1883C>A p.A628E (on ENST00000356141 / NM_001164749.2; = p.A596E on NM_022123.3) | Missense Mutation (SNP) | VAF 94/517 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.028); catalogued as rs146571623; called by muse, mutect2, varscan2
- NPHP4 | c.673G>T p.G225C | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs540402276, CM139054, COSV65393214, COSV65395328; called by muse, mutect2, varscan2
- NPR3 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as rs1156299137; called by muse, mutect2, varscan2
- NPY2R | c.721C>G p.R241G | Missense Mutation (SNP) | VAF 125/404 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.832); catalogued as rs569808445, COSV61528652; called by muse, mutect2, varscan2
- NPY5R | c.893C>A p.P298H | Missense Mutation (SNP) | VAF 93/251 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100642993; called by muse, mutect2, varscan2
- NSRP1 | c.21-1G>T p.X7_splice | Splice Site (SNP) | VAF 25/124 reads (20%) | catalogued as COSV55935139; called by muse, mutect2, varscan2
- NTNG2 | c.574C>A p.R192S | Missense Mutation (SNP) | VAF 65/290 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs765705117, COSV100647173; called by muse, mutect2, varscan2
- NUTM1 | c.1033C>A p.R345S | Missense Mutation (SNP) | VAF 117/546 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as COSV59218131; called by muse, mutect2, varscan2
- OBSCN | c.11561G>A p.R3854K | Missense Mutation (SNP) | VAF 79/552 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV52779605; called by muse, mutect2, varscan2
- OCA2 | c.988C>A p.Q330K | Missense Mutation (SNP) | VAF 86/407 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.776); catalogued as COSV62355445; called by muse, mutect2, varscan2
- OR10K2 | c.718A>T p.T240S | Missense Mutation (SNP) | VAF 69/275 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100149682; called by muse, mutect2, varscan2
- OR14C36 | c.604C>A p.L202M | Missense Mutation (SNP) | VAF 84/245 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.513); catalogued as COSV58602630; called by muse, mutect2, varscan2
- OR1A2 | c.335G>T p.S112I | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV101126394; called by muse, mutect2, varscan2
- OR1D2 | c.62C>A p.P21H | Missense Mutation (SNP) | VAF 116/468 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58921725; called by muse, mutect2, varscan2
- OR1D2 | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 115/461 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58921732; called by muse, mutect2, varscan2
- OR2W3 | c.825G>C p.M275I | Missense Mutation (SNP) | VAF 48/344 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV64457734; called by mutect2, varscan2
- OR4D9 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV61434610; called by muse, mutect2, varscan2
- OR4F15 | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 75/250 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV100173883; called by muse, mutect2, varscan2
- OR4P4 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs143338269, COSV58923294; called by muse, mutect2, varscan2
- OR4Q3 | c.687C>G p.I229M | Missense Mutation (SNP) | VAF 58/598 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV59177386; called by muse, mutect2
- OR51B5 | c.537C>A p.H179Q | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs150082635; called by muse, mutect2, varscan2
- OR52A5 | c.717G>C p.K239N | Missense Mutation (SNP) | VAF 97/371 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56614536, COSV56616097; called by muse, mutect2, varscan2
- OR52N1 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 236/509 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1454218831; called by muse, mutect2, varscan2
- OR52R1 | c.180G>T p.E60D | Missense Mutation (SNP) | VAF 140/287 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV100617663, COSV100617743; called by muse, mutect2, varscan2
- OR8D4 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV58429312; called by muse, mutect2, varscan2
- OR9G1 | c.106C>T p.L36F | Missense Mutation (SNP) | VAF 116/869 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs749208165; called by muse, mutect2, varscan2
- OSBPL5 | c.2398+1G>T p.X800_splice | Splice Site (SNP) | VAF 66/141 reads (47%) | catalogued as COSV99720299; called by muse, mutect2, varscan2
- OTOA | c.1286C>A p.S429Y (on ENST00000286149; = p.S415Y on NM_144672.4) | Missense Mutation (SNP) | VAF 153/476 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV53766642; called by muse, mutect2, varscan2
- P4HTM | c.1486C>G p.R496G (on ENST00000383729 / NM_177939.3; = p.R557G on NM_177938.2) | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs748158739; called by muse, mutect2, varscan2
- PABPC1 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as rs1464103447; called by muse, mutect2
- PCDH11Y | c.145G>C p.V49L (on ENST00000400457 / NM_032973.2; = p.V38L on NM_032971.3) | Missense Mutation (SNP) | VAF 150/504 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV99292855; called by muse, mutect2, varscan2
- PCDH15 | c.4312C>T p.P1438S | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.028); catalogued as rs779149856; called by muse, mutect2, varscan2
- PCDHA12 | c.1087G>T p.A363S | Missense Mutation (SNP) | VAF 106/269 reads (39%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.547); catalogued as COSV56493166; called by muse, mutect2, varscan2
- PCDHGA1 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 93/272 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.118); catalogued as COSV65295207; called by muse, mutect2, varscan2
- PERM1 | c.1828G>T p.V610F | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs556313468; called by muse, mutect2, varscan2
- PEX7 | c.618G>T p.W206C | Missense Mutation (SNP) | VAF 66/401 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM022442; called by muse, mutect2, varscan2
- PIAS3 | c.461G>C p.R154P | Missense Mutation (SNP) | VAF 51/358 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV65172290; called by muse, mutect2, varscan2
- PIK3C2G | c.2426G>T p.W809L (on ENST00000676171; = p.W768L on NM_004570.5) | Missense Mutation (SNP) | VAF 83/234 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.849); catalogued as COSV56829808; called by muse, mutect2, varscan2
- PKD1L1 | c.8128C>T p.Q2710* | Nonsense Mutation (SNP) | VAF 91/581 reads (16%) | catalogued as rs1367784047; called by muse, mutect2, varscan2
- PLAUR | c.23C>A p.P8Q | Missense Mutation (SNP) | VAF 38/239 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.021); catalogued as rs867018678; called by muse, mutect2, varscan2
- PLCH1 | c.1807G>T p.D603Y (on ENST00000340059 / NM_001130960.2; = p.D615Y on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100396910, COSV100397012, COSV58208727; called by muse, mutect2, varscan2
- PLPPR1 | c.662C>A p.T221K | Missense Mutation (SNP) | VAF 78/198 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as rs200667385; called by muse, mutect2, varscan2
- PLPPR4 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV64566718, COSV64567471; called by muse, mutect2, varscan2
- PMM1 | c.385A>G p.I129V | Missense Mutation (SNP) | VAF 60/268 reads (22%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.886); catalogued as rs756271118; called by muse, mutect2, varscan2
- PNPLA6 | c.654G>T p.Q218H (on ENST00000414982 / NM_001166111.2; = p.Q170H on NM_006702.5) | Missense Mutation (SNP) | VAF 115/285 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55379744; called by muse, mutect2, varscan2
- POC1B | c.1220A>G p.K407R | Missense Mutation (SNP) | VAF 39/657 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.142); catalogued as rs1337041775; called by muse, mutect2
- POLR3B | c.846G>T p.Q282H | Missense Mutation (SNP) | VAF 115/429 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV99942872; called by muse, mutect2, varscan2
- POM121L12 | c.742T>A p.C248S | Missense Mutation (SNP) | VAF 43/320 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.161); catalogued as COSV101374921, COSV101374957; called by muse, mutect2, varscan2
- POTEE | c.2696G>T p.R899M | Missense Mutation (SNP) | VAF 128/1819 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.046); catalogued as rs769501012; called by muse, mutect2
- POTEF | c.2696G>T p.R899M | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs757575217; called by muse, mutect2, varscan2
- POTEF | c.330G>T p.R110S | Missense Mutation (SNP) | VAF 72/584 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.227); catalogued as COSV62545097; called by mutect2, varscan2
- PPP1R3C | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 67/480 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780724553; called by muse, mutect2, varscan2
- PPP4R3C | c.2156T>C p.L719P | Missense Mutation (SNP) | VAF 147/313 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.086); catalogued as rs982320155; called by muse, mutect2, varscan2
- PRAMEF19 | c.1085G>T p.G362V | Missense Mutation (SNP) | VAF 169/972 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs368133486; called by muse, mutect2, varscan2
- PRDM14 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV52573421; called by muse, mutect2, varscan2
- PROKR1 | c.38C>A p.T13N | Missense Mutation (SNP) | VAF 35/245 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV58138446; called by muse, mutect2, varscan2
- PRPF40A | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs764554990; called by muse, mutect2, varscan2
- PRR19 | c.870G>A p.W290* | Nonsense Mutation (SNP) | VAF 54/227 reads (24%) | catalogued as COSV100004193; called by muse, mutect2, varscan2
- PSG6 | c.686C>G p.P229R | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866550375; called by muse, mutect2, varscan2
- PTCD1 | c.1085G>T p.R362L | Missense Mutation (SNP) | VAF 47/297 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52866880; called by muse, mutect2, varscan2
- PTPRQ | c.4964C>T p.T1655I (on ENST00000616559; = p.T1613I on NM_001145026.2) | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.041); catalogued as rs980102512; called by muse, mutect2
- PTPRT | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100625375, COSV61999164; called by muse, mutect2, varscan2
- PTPRU | c.1869-1G>T p.X623_splice | Splice Site (SNP) | VAF 29/133 reads (22%) | catalogued as COSV100113483; called by muse, mutect2, varscan2
- PXDNL | c.3800T>G p.V1267G | Missense Mutation (SNP) | VAF 64/396 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753916715; called by muse, mutect2, varscan2
- RBMXL2 | c.908G>T p.G303V | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.831); catalogued as COSV60979835; called by muse, mutect2, varscan2
- RELN | c.2531C>A p.P844Q | Missense Mutation (SNP) | VAF 166/429 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as CM155181, COSV100633129, COSV59030327; called by muse, mutect2, varscan2
- RFX6 | c.2512C>A p.H838N | Missense Mutation (SNP) | VAF 89/492 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV60587739; called by muse, mutect2, varscan2
- RGPD3 | c.2306T>G p.L769W | Missense Mutation (SNP) | VAF 192/1259 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs746405048; called by muse, mutect2, varscan2
- RNF207 | c.1549C>T p.L517F | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs780573668, COSV65007376; called by muse, mutect2, varscan2
- RP1L1 | c.5247C>A p.S1749R | Missense Mutation (SNP) | VAF 64/362 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.22); catalogued as rs778715898; called by muse, mutect2, varscan2
- RPS6KA2 | c.1105G>C p.A369P | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.917); catalogued as rs936064171; called by muse, mutect2, varscan2
- RSBN1 | c.1086G>T p.E362D | Missense Mutation (SNP) | VAF 72/399 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as COSV54732888; called by muse, mutect2, varscan2
- RUVBL1 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 56/262 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100494084; called by muse, mutect2, varscan2
- RUVBL2 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 54/333 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1269951930; called by muse, mutect2, varscan2
- RYR3 | c.7792G>T p.D2598Y (on ENST00000389232; = p.D2599Y on NM_001036.6) | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1291040362, COSV66807674; called by muse, mutect2, varscan2
- SALL3 | c.3562G>T p.D1188Y | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV73305954; called by muse, mutect2, varscan2
- SCD | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 53/347 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs900799696; called by muse, mutect2, varscan2
- SCN4A | c.4518C>A p.Y1506* | Nonsense Mutation (SNP) | VAF 72/511 reads (14%) | catalogued as COSV71125982; called by muse, mutect2, varscan2
- SCN7A | c.1884A>C p.K628N | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101313255; called by muse, mutect2, varscan2
- SCYL1 | c.1103G>T p.R368L | Missense Mutation (SNP) | VAF 44/319 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs187644314; called by muse, mutect2, varscan2
- SEC14L5 | c.727G>T p.E243* | Nonsense Mutation (SNP) | VAF 12/296 reads (4%) | catalogued as COSV52040376; called by muse, mutect2
- SERPINB5 | c.1035G>C p.K345N | Missense Mutation (SNP) | VAF 37/321 reads (12%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.998); catalogued as rs373768833; called by muse, mutect2, varscan2
- SERPING1 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 119/414 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs1249531471, COSV53541600, COSV99558197; called by muse, mutect2, varscan2
- SHROOM2 | c.4282G>T p.D1428Y | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV66605395; called by muse, mutect2
- SHROOM3 | c.3596C>G p.T1199S | Missense Mutation (SNP) | VAF 83/379 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV56024236; called by muse, mutect2, varscan2
- SIGLEC5 | c.739G>C p.A247P | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as COSV55784695; called by muse, mutect2, varscan2
- SIRPA | c.304A>G p.M102V | Missense Mutation (SNP) | VAF 235/743 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.025); catalogued as rs142085206; called by muse, mutect2, varscan2
- SLAMF6 | c.100C>A p.L34M | Missense Mutation (SNP) | VAF 90/238 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100924883; called by muse, mutect2, varscan2
- SLC12A1 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV100372360; called by muse, mutect2, varscan2
- SLC12A1 | c.2105A>G p.H702R | Missense Mutation (SNP) | VAF 62/376 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.183); catalogued as COSV66791501; called by muse, mutect2, varscan2
- SLC17A1 | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55078651, COSV55082512; called by muse, varscan2
- SLC17A1 | c.530-1G>C p.X177_splice | Splice Site (SNP) | VAF 24/137 reads (18%) | catalogued as COSV55082406, COSV99765672; called by muse, mutect2, varscan2
- SLC17A6 | c.1586G>T p.G529V | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.147); catalogued as COSV54140615; called by muse, mutect2
- SLC27A6 | c.269G>A p.S90N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs760669811; called by muse, mutect2, varscan2
- SLC35A4 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 57/271 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs776343678; called by muse, mutect2, varscan2
- SLC35G5 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 282/886 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs532136763, COSV55312683; called by muse, mutect2, varscan2
- SLC5A7 | c.1137G>T p.W379C | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV99887156; called by muse, mutect2, varscan2
- SLITRK3 | c.2749C>G p.P917A | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1407774822; called by muse, mutect2, varscan2
- SMAP2 | c.572-1G>T p.X191_splice | Splice Site (SNP) | VAF 34/136 reads (25%) | catalogued as COSV101019356; called by muse, mutect2, varscan2
- SMG1 | c.10705A>T p.T3569S | Missense Mutation (SNP) | VAF 64/223 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV67173792; called by muse, mutect2, varscan2
- SMPDL3A | c.829G>T p.D277Y | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV100868727; called by muse, mutect2, varscan2
- SNTN | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs780135430; called by muse, mutect2, varscan2
- SORCS3 | c.2128G>T p.G710* | Nonsense Mutation (SNP) | VAF 68/218 reads (31%) | catalogued as COSV100863920; called by muse, mutect2, varscan2
- SPEF2 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 35/360 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.373); catalogued as rs368259023; called by muse, mutect2, varscan2
- SPTA1 | c.4839C>G p.N1613K | Missense Mutation (SNP) | VAF 81/1026 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.838); catalogued as COSV63758010; called by muse, mutect2
- SPTA1 | c.3570-1G>A p.X1190_splice | Splice Site (SNP) | VAF 281/589 reads (48%) | catalogued as COSV100935530; called by muse, mutect2, varscan2
- SPTAN1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 42/661 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM147766; called by muse, mutect2
- SPTBN1 | c.5761C>A p.R1921S | Missense Mutation (SNP) | VAF 68/389 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100442594; called by muse, mutect2, varscan2
- SSTR4 | c.461_462del p.A154Gfs*135 | Frame Shift Del (DEL) | VAF 22/184 reads (12%) | catalogued as rs1471704463; called by pindel, varscan2
- STAB1 | c.5489G>T p.R1830L | Missense Mutation (SNP) | VAF 65/359 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as COSV58739787; called by muse, mutect2, varscan2
- STAT2 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 48/465 reads (10%) | catalogued as COSV58474703; called by muse, mutect2, varscan2
- SUGP2 | c.1507G>T p.G503C | Missense Mutation (SNP) | VAF 108/278 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58254961; called by muse, mutect2, varscan2
- SV2A | c.1471C>G p.R491G | Missense Mutation (SNP) | VAF 35/322 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV100975315; called by muse, mutect2, varscan2
- SYNE1 | c.1433C>T p.P478L (on ENST00000367255 / NM_182961.4; = p.P485L on NM_033071.3) | Missense Mutation (SNP) | VAF 62/266 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.247); catalogued as COSV54895147; called by muse, mutect2, varscan2
- SYNPO2 | c.929C>G p.S310C | Missense Mutation (SNP) | VAF 85/217 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV61114434, COSV61114607; called by muse, mutect2, varscan2
- TBX4 | c.1439C>A p.S480Y | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); catalogued as COSV53606177; called by muse, mutect2
- TBX5 | c.97G>C p.G33R | Missense Mutation (SNP) | VAF 84/514 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV100092500; called by muse, mutect2, varscan2
- TCF20 | c.3766C>T p.R1256C | Missense Mutation (SNP) | VAF 37/341 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs143040769; called by muse, mutect2, varscan2
- TCF7L1 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 60/323 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1384903688; called by muse, mutect2, varscan2
- TECRL | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 106/305 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.62); catalogued as COSV101169482; called by muse, varscan2
- TENM2 | c.1935C>A p.C645* (on ENST00000518659 / NM_001122679.2; = p.C413* on NM_001080428.3) | Nonsense Mutation (SNP) | VAF 17/67 reads (25%) | catalogued as rs755299086, COSV69128984, COSV69140214; called by muse, mutect2, varscan2
- TENM2 | c.5413C>T p.R1805C (on ENST00000518659 / NM_001122679.2; = p.R1566C on NM_001080428.3) | Missense Mutation (SNP) | VAF 115/300 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs371071052; called by muse, mutect2, varscan2
- TET3 | c.3013C>T p.R1005C | Missense Mutation (SNP) | VAF 46/253 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69641964, COSV99081447; called by muse, mutect2, varscan2
- TGM5 | c.2102G>A p.R701K (on ENST00000220420 / NM_201631.4; = p.R619K on NM_004245.4) | Missense Mutation (SNP) | VAF 71/421 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV55011767; called by muse, mutect2, varscan2
- TIGD5 | c.137T>C p.V46A | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated, low confidence (0.25); catalogued as rs895704615; called by muse, mutect2
- TIMM13 | c.48G>T p.K16N | Missense Mutation (SNP) | VAF 100/286 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.264); catalogued as rs1245861531; called by muse, mutect2, varscan2
- TM6SF1 | c.893C>G p.T298R | Missense Mutation (SNP) | VAF 111/347 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs1290288352; called by muse, mutect2, varscan2
- TM7SF2 | c.599G>A p.G200D | Missense Mutation (SNP) | VAF 70/391 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1408778642, COSV99659532; called by muse, mutect2, varscan2
- TMEM132A | c.1271G>C p.R424P (on ENST00000453848 / NM_178031.3; = p.R425P on NM_017870.4) | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV50007759; called by muse, mutect2
- TMEM178A | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs759716501, COSV56143388; called by muse, mutect2, varscan2
- TMTC1 | c.846A>T p.K282N (on ENST00000539277 / NM_001193451.2; = p.K174N on NM_175861.3) | Missense Mutation (SNP) | VAF 47/283 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.062); catalogued as rs1235867622; called by muse, mutect2, varscan2
- TMX2 | c.554A>G p.N185S | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.13); catalogued as rs768799368; called by muse, mutect2, varscan2
- TNKS | c.3539G>C p.R1180P | Missense Mutation (SNP) | VAF 55/216 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60051071; called by muse, mutect2, varscan2
- TNP1 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52696403, COSV52697086; called by muse, mutect2, varscan2
- TOR3A | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 87/213 reads (41%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV61680415; called by muse, mutect2, varscan2
- TPO | c.2603C>T p.T868M | Missense Mutation (SNP) | VAF 110/631 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as rs201576336; called by muse, mutect2, varscan2
- TRAF2 | c.1204G>A p.G402R | Missense Mutation (SNP) | VAF 91/235 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs776552418; called by muse, mutect2, varscan2
- TRGV3 | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 126/710 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1019578671; called by muse, mutect2, varscan2
- TRIM3 | c.1318G>T p.G440C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV61983521; called by muse, mutect2
- TRIM6-TRIM34 | c.1759C>A p.L587I | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61456861; called by muse, mutect2, varscan2
- TRMT2A | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1568973506; called by muse, mutect2, varscan2
- TRPA1 | c.3038G>T p.G1013V | Missense Mutation (SNP) | VAF 48/530 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV100084133, COSV51569900; called by muse, mutect2
- TSPOAP1 | c.4822G>A p.A1608T | Missense Mutation (SNP) | VAF 50/233 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776880373; called by muse, mutect2, varscan2
- TSPOAP1 | c.3190G>T p.G1064W | Missense Mutation (SNP) | VAF 134/411 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99272546; called by muse, mutect2, varscan2
- TTC34 | c.2845G>T p.E949* | Nonsense Mutation (SNP) | VAF 47/249 reads (19%) | catalogued as rs917164975; called by muse, mutect2, varscan2
- TTN | c.95297A>T p.D31766V (on ENST00000591111; = p.D24342V on NM_003319.4) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | PolyPhen possibly damaging (0.79); catalogued as COSV100594890; called by muse, varscan2
- UBE4A | c.632G>T p.R211L | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV52803869; called by muse, mutect2, varscan2
- UGP2 | c.255+1G>T p.X85_splice | Splice Site (SNP) | VAF 43/183 reads (23%) | catalogued as rs1210609793; called by muse, mutect2, varscan2
- UGT1A10 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 63/309 reads (20%) | catalogued as COSV60832263; called by muse, mutect2, varscan2
- UGT3A1 | c.304del p.D102Mfs*10 | Frame Shift Del (DEL) | VAF 62/337 reads (18%) | catalogued as COSV99954662; called by mutect2, pindel, varscan2
- UNC5D | c.1123del p.E375Rfs*46 | Frame Shift Del (DEL) | VAF 25/99 reads (25%) | catalogued as COSV54779953; called by mutect2, pindel, varscan2
- UNC80 | c.2631G>T p.K877N | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as COSV55904458; called by muse, mutect2, varscan2
- URB2 | c.3316G>T p.G1106W | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs766418966; called by muse, mutect2, varscan2
- USH2A | c.5751C>A p.Y1917* | Nonsense Mutation (SNP) | VAF 125/375 reads (33%) | catalogued as CM149921; called by muse, mutect2, varscan2
- USP17L2 | c.556C>A p.H186N | Missense Mutation (SNP) | VAF 78/826 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV100414787; called by muse, mutect2, varscan2
- USP40 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs774211792; called by muse, mutect2, varscan2
- VPREB1 | c.327C>A p.D109E | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs377536245, COSV56426685; called by muse, mutect2, varscan2
- VWA1 | c.264C>A p.F88L | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.695); catalogued as COSV58599916; called by muse, mutect2, varscan2
- VWA3B | c.2827C>A p.Q943K | Missense Mutation (SNP) | VAF 65/201 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV68245866; called by muse, mutect2, varscan2
- VWDE | c.820G>T p.E274* | Nonsense Mutation (SNP) | VAF 34/234 reads (15%) | catalogued as rs1231739475; called by muse, mutect2, varscan2
- WIPF1 | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as COSV99769586; called by muse, mutect2
- ZC3H3 | c.2756C>T p.P919L | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs759251402; called by muse, varscan2
- ZDHHC11 | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376637668; called by mutect2, varscan2
- ZFHX4 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 128/343 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs746502584, COSV50610942; called by muse, mutect2, varscan2
- ZFPM2 | c.485G>A p.W162* | Nonsense Mutation (SNP) | VAF 51/403 reads (13%) | catalogued as COSV68286846; called by muse, mutect2, varscan2
- ZNF304 | c.539C>A p.S180Y | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.556); catalogued as COSV56585651, COSV56585708; called by muse, mutect2, varscan2
- ZNF536 | c.2066C>T p.P689L | Missense Mutation (SNP) | VAF 97/284 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62821476; called by muse, mutect2, varscan2
- ZNF536 | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751094459, COSV62825355; called by muse, mutect2, varscan2
- ZNF648 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 160/387 reads (41%) | catalogued as COSV60569859; called by muse, mutect2, varscan2
- ZNF676 | c.195G>T p.M65I (on ENST00000650058; = p.M33I on NM_001001411.3) | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.216); catalogued as COSV68093096; called by muse, mutect2, varscan2
- ZP4 | c.1243C>A p.Q415K | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.361); catalogued as COSV100850626; called by muse, mutect2, varscan2
- ZP4 | c.1242C>A p.H414Q | Missense Mutation (SNP) | VAF 54/221 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV63912112; called by muse, mutect2, varscan2
- ZSCAN4 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 67/315 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs765340909; called by muse, mutect2, varscan2
- AACS | c.1024G>C p.V342L | Missense Mutation (SNP) | VAF 101/308 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- AATK | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 78/251 reads (31%) | called by muse, mutect2, varscan2
- ABCC3 | c.2699A>T p.Q900L | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ACACA | c.2953C>G p.H985D | Missense Mutation (SNP) | VAF 46/523 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACAP1 | c.266A>G p.H89R | Missense Mutation (SNP) | VAF 49/390 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ACAP2 | c.2336G>T p.*779Lext*12 | Nonstop Mutation (SNP) | VAF 36/162 reads (22%) | called by muse, mutect2, varscan2
- ACLY | c.1632del p.H545Tfs*5 | Frame Shift Del (DEL) | VAF 33/127 reads (26%) | called by mutect2, pindel, varscan2
- ACTG2 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- ACTRT1 | c.518C>A p.S173Y | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ADAM20 | c.598G>T p.V200L | Missense Mutation (SNP) | VAF 55/279 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS18 | c.3442G>C p.V1148L | Missense Mutation (SNP) | VAF 104/259 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ADAMTS19 | c.1965C>G p.C655W | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS3 | c.809G>T p.R270L | Missense Mutation (SNP) | VAF 121/335 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ADAMTSL2 | c.736G>C p.E246Q | Missense Mutation (SNP) | VAF 241/593 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTSL3 | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 67/310 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADCY8 | c.2417G>A p.W806* | Nonsense Mutation (SNP) | VAF 40/266 reads (15%) | called by muse, varscan2
- ADCY8 | c.190G>T p.G64C | Missense Mutation (SNP) | VAF 88/205 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ADGRA2 | c.2017G>A p.G673S | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADGRE1 | c.1675G>T p.G559C | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ADGRF5 | c.157+1G>T p.X53_splice | Splice Site (SNP) | VAF 31/195 reads (16%) | called by muse, mutect2, varscan2
- ADHFE1 | c.338A>T p.E113V | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ADNP | c.2243A>G p.E748G | Missense Mutation (SNP) | VAF 23/316 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); called by muse, mutect2
- ADRB1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- AFAP1L1 | c.905A>T p.E302V | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AGBL4 | c.893G>T p.W298L | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- AIPL1 | c.782C>A p.P261Q | Missense Mutation (SNP) | VAF 56/326 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- AIRE | c.803G>T p.G268V | Missense Mutation (SNP) | VAF 108/285 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- AKAP13 | c.1527G>T p.E509D | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- AKAP8L | c.757G>T p.G253C | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AL133500.1 | c.1511C>A p.P504Q | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- ALLC | c.391G>T p.D131Y | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- AMER3 | c.648C>A p.D216E | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.624); called by muse, varscan2
- AMER3 | c.696G>T p.R232S | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.012); called by muse, varscan2
- AMY2A | c.413G>T p.S138I | Missense Mutation (SNP) | VAF 26/416 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ANGPTL5 | c.1097A>G p.N366S | Missense Mutation (SNP) | VAF 85/224 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- ANKFN1 | c.3580C>A p.L1194M (on ENST00000653862; = p.L1047M on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/305 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ANKRD30B | c.2608A>G p.T870A | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ANKRD30B | c.3299C>A p.T1100K | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- ANKRD49 | c.432_433insT p.L145Sfs*6 | Frame Shift Ins (INS) | VAF 127/481 reads (26%) | called by mutect2, pindel, varscan2
- ANKS3 | c.205G>T p.G69C | Missense Mutation (SNP) | VAF 95/377 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AP4B1 | c.1948G>A p.G650R | Missense Mutation (SNP) | VAF 58/379 reads (15%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- APOB | c.13128G>T p.Q4376H | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- APOL2 | c.865G>C p.V289L | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- ARHGAP22 | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 52/376 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ARHGAP23 | c.3182G>C p.G1061A | Missense Mutation (SNP) | VAF 67/333 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ARHGEF37 | c.1708del p.V570Sfs*13 | Frame Shift Del (DEL) | VAF 65/209 reads (31%) | called by mutect2, pindel, varscan2
- ARID3A | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 81/477 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ARID5B | c.2066dup p.L690Tfs*36 | Frame Shift Ins (INS) | VAF 25/130 reads (19%) | called by mutect2, pindel, varscan2
- ARL14EP | c.356G>C p.C119S | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ARMC12 | c.539C>A p.P180H (on ENST00000373866 / NM_001286574.2; = p.P207H on NM_145028.5) | Missense Mutation (SNP) | VAF 69/353 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ARRDC3 | c.1189-2A>G p.X397_splice | Splice Site (SNP) | VAF 40/130 reads (31%) | called by muse, mutect2, varscan2
- ARSA | c.158A>T p.Q53L | Missense Mutation (SNP) | VAF 57/289 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ASAH2 | c.1259C>A p.T420K | Missense Mutation (SNP) | VAF 77/533 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ASB17 | c.566C>A p.P189H | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ASMT | c.161G>T p.R54M | Missense Mutation (SNP) | VAF 137/971 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- ASTN1 | c.3755G>T p.G1252V | Missense Mutation (SNP) | VAF 47/502 reads (9%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.023); called by muse, mutect2
- ASTN1 | c.307A>T p.I103F | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- ATAD3A | c.341G>C p.R114P | Missense Mutation (SNP) | VAF 80/423 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ATP12A | c.43G>T p.G15* | Nonsense Mutation (SNP) | VAF 44/168 reads (26%) | called by muse, mutect2
- ATP1A2 | c.2072C>A p.S691Y | Missense Mutation (SNP) | VAF 320/744 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP1B1 | c.135_142del p.C45Wfs*16 | Frame Shift Del (DEL) | VAF 35/296 reads (12%) | called by mutect2, pindel, varscan2
- ATP9B | c.1031-1G>T p.X344_splice | Splice Site (SNP) | VAF 33/124 reads (27%) | called by muse, mutect2, varscan2
- ATXN3L | c.502G>C p.D168H | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- AXIN2 | c.1321G>T p.D441Y | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- B3GALT6 | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.066); called by muse, mutect2
- BAHCC1 | c.6806G>T p.G2269V | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- BARHL2 | c.170C>G p.T57S | Missense Mutation (SNP) | VAF 141/433 reads (33%) | SIFT tolerated, low confidence (0.66); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- BCL11A | c.2194G>T p.G732C (on ENST00000335712 / NM_001365609.1; = p.G766C on NM_022893.4) | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BMP7 | c.73C>A p.R25S | Missense Mutation (SNP) | VAF 32/608 reads (5%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2
- BNIPL | c.700G>T p.V234F | Missense Mutation (SNP) | VAF 35/386 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); called by muse, mutect2
- BOD1L1 | c.5557G>T p.G1853C | Missense Mutation (SNP) | VAF 55/287 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- BRINP3 | c.1838C>T p.T613I | Missense Mutation (SNP) | VAF 51/343 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- BRINP3 | c.1837A>C p.T613P | Missense Mutation (SNP) | VAF 50/340 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- BRINP3 | c.1534G>T p.A512S | Missense Mutation (SNP) | VAF 107/325 reads (33%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- BUB1B | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 58/317 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C10orf71 | c.3374C>A p.P1125H | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- C19orf44 | c.1231G>T p.A411S | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C2CD4A | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- C2orf16 | c.4938T>A p.H1646Q | Missense Mutation (SNP) | VAF 146/773 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- C4orf54 | c.2551G>T p.A851S | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- C4orf54 | c.2224C>G p.Q742E | Missense Mutation (SNP) | VAF 75/191 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- C6orf52 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CA2 | c.35-1G>T p.X12_splice | Splice Site (SNP) | VAF 28/229 reads (12%) | called by muse, mutect2, varscan2
- CABS1 | c.529C>G p.P177A | Missense Mutation (SNP) | VAF 94/256 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- CACNA1G | c.5878C>A p.P1960T | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CACNA2D1 | c.1171C>A p.Q391K | Missense Mutation (SNP) | VAF 64/410 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CACNG3 | c.428T>A p.V143D | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- CACNG6 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 57/263 reads (22%) | called by muse, mutect2, varscan2
- CALCR | c.-27G>T | Splice Region (SNP) | VAF 23/225 reads (10%) | called by muse, mutect2, varscan2
- CALD1 | c.2210G>T p.G737V (on ENST00000361675 / NM_033138.4; = p.G482V on NM_004342.7) | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- CAMKV | c.228G>T p.M76I | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CAPSL | c.567C>A p.S189R | Missense Mutation (SNP) | VAF 108/333 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CASP8AP2 | c.3365A>T p.Q1122L | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CASR | c.1702G>T p.A568S (on ENST00000490131; = p.A645S on NM_000388.4) | Missense Mutation (SNP) | VAF 77/150 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC168 | c.16312A>G p.N5438D | Missense Mutation (SNP) | VAF 48/294 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CCDC74A | c.1124G>T p.R375L | Missense Mutation (SNP) | VAF 76/202 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCL26 | c.109T>C p.Y37H | Missense Mutation (SNP) | VAF 44/334 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- CCNE1 | c.662G>T p.C221F | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CCNE1 | c.798_800dup p.L267dup | In Frame Ins (INS) | VAF 31/120 reads (26%) | called by mutect2, pindel, varscan2
- CCT8L2 | c.1210C>A p.Q404K | Missense Mutation (SNP) | VAF 89/432 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CD300E | c.582G>C p.W194C | Missense Mutation (SNP) | VAF 45/231 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD33 | c.397C>A p.Q133K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CDA | c.216G>T p.Q72H | Missense Mutation (SNP) | VAF 136/651 reads (21%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- CDH10 | c.1694C>A p.P565H | Missense Mutation (SNP) | VAF 65/462 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH12 | c.2288A>T p.Q763L | Missense Mutation (SNP) | VAF 194/480 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- CDH17 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 122/261 reads (47%) | called by muse, mutect2, varscan2
- CDH18 | c.2227C>A p.Q743K | Missense Mutation (SNP) | VAF 75/532 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CDH2 | c.1990C>A p.L664I | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.272); called by muse, mutect2
- CDH23 | c.5113G>T p.G1705C | Missense Mutation (SNP) | VAF 60/455 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH23 | c.8660C>A p.A2887D | Missense Mutation (SNP) | VAF 24/401 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.287); called by muse, mutect2
- CDH5 | c.2111A>T p.E704V | Missense Mutation (SNP) | VAF 221/526 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CDH8 | c.1675del p.A559Qfs*19 | Frame Shift Del (DEL) | VAF 133/336 reads (40%) | called by mutect2, pindel, varscan2
- CDH8 | c.265C>A p.L89M | Missense Mutation (SNP) | VAF 73/155 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CDK12 | c.926G>C p.R309P | Missense Mutation (SNP) | VAF 18/557 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CDK6 | c.342G>T p.E114D | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDS2 | c.1177G>C p.V393L | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- CEACAM20 | c.1575G>A p.L525= | Splice Region (SNP) | VAF 45/195 reads (23%) | called by muse, mutect2, varscan2
- CEACAM7 | c.325C>A p.L109M | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CENPE | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CENPF | c.8710G>T p.G2904C | Missense Mutation (SNP) | VAF 106/275 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CEP97 | c.1995T>G p.H665Q | Missense Mutation (SNP) | VAF 110/257 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CER1 | c.716G>T p.C239F | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP251 | c.2686G>T p.G896C | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- CFAP52 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- CHAT | c.1941C>A p.Y647* | Nonsense Mutation (SNP) | VAF 160/846 reads (19%) | called by muse, mutect2, varscan2
- CHAT | c.1942C>A p.L648M | Missense Mutation (SNP) | VAF 162/854 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- CHD5 | c.5742G>T p.Q1914H | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- CHD8 | c.2430G>T p.Q810H (on ENST00000646647 / NM_001170629.2; = p.Q531H on NM_020920.4) | Missense Mutation (SNP) | VAF 92/361 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- CHL1 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CHRNA6 | c.291G>A p.W97* | Nonsense Mutation (SNP) | VAF 30/191 reads (16%) | called by muse, mutect2, varscan2
- CILP | c.557G>T p.S186I | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- CILP2 | c.1537G>T p.V513L | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- CIT | c.78G>T p.R26S | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CLASRP | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 32/237 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CLSTN2 | c.1382T>C p.V461A | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- CLUH | c.2660C>A p.A887D (on ENST00000435359; = p.A926D on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CNGA1 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 58/354 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CNGB3 | c.2000C>A p.P667Q | Missense Mutation (SNP) | VAF 87/586 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- CNNM2 | c.1707A>T p.L569F | Missense Mutation (SNP) | VAF 40/231 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CNTN1 | c.107del p.D36Afs*44 | Frame Shift Del (DEL) | VAF 56/483 reads (12%) | called by mutect2, pindel, varscan2
- CNTN6 | c.1010G>C p.W337S | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTNAP5 | c.1122C>A p.S374R | Missense Mutation (SNP) | VAF 141/419 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNTNAP5 | c.1940C>A p.P647H | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- COL11A2 | c.4021C>T p.P1341S (on ENST00000341947 / NM_080680.3; = p.P1234S on NM_080679.2) | Missense Mutation (SNP) | VAF 137/644 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL12A1 | c.5911G>T p.V1971L | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL1A2 | c.156A>T p.R52S | Missense Mutation (SNP) | VAF 137/446 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- COL5A1 | c.4453C>A p.P1485T | Missense Mutation (SNP) | VAF 198/503 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL5A2 | c.3986A>T p.N1329I | Missense Mutation (SNP) | VAF 43/280 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL6A6 | c.5441G>T p.R1814L | Missense Mutation (SNP) | VAF 29/209 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COPS5 | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- COX18 | c.168G>T p.E56D | Missense Mutation (SNP) | VAF 120/580 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- CPS1 | c.2155C>A p.L719M | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRACR2A | c.543G>T p.Q181H | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- CRB1 | c.3881G>T p.C1294F | Missense Mutation (SNP) | VAF 141/444 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRISPLD1 | c.1363_1364del p.R455Kfs*7 | Frame Shift Del (DEL) | VAF 32/280 reads (11%) | called by mutect2, pindel*
- CROCC2 | c.4760A>T p.D1587V | Missense Mutation (SNP) | VAF 42/336 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- CRYBG3 | c.7180T>A p.F2394I | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CSDE1 | c.1691A>G p.Y564C (on ENST00000358528 / NM_001007553.3; = p.Y533C on NM_007158.6) | Missense Mutation (SNP) | VAF 77/404 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- CSH1 | c.144G>T p.Q48H | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CSH1 | c.143A>T p.Q48L | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CSH2 | c.143A>T p.Q48L | Missense Mutation (SNP) | VAF 97/940 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.264); called by muse, mutect2
- CSMD1 | c.8101G>T p.D2701Y (on ENST00000520002; = p.D2700Y on NM_033225.6) | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSMD3 | c.3584G>T p.G1195V (on ENST00000297405 / NM_001363185.1; = p.G1091V on NM_052900.3) | Missense Mutation (SNP) | VAF 271/695 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CSPG4 | c.1704C>A p.H568Q | Missense Mutation (SNP) | VAF 100/340 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- CST4 | c.395C>A p.S132Y | Missense Mutation (SNP) | VAF 106/463 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CTNND1 | c.920G>C p.R307P | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- CYP2J2 | c.232C>A p.L78I | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP2W1 | c.1378C>A p.P460T | Missense Mutation (SNP) | VAF 102/302 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYRIB | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CYSLTR1 | c.423G>T p.R141S | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- DAB1 | c.902G>T p.G301V (on ENST00000371231; = p.G268V on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- DAB1 | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- DACT3 | c.145C>A p.Q49K | Missense Mutation (SNP) | VAF 68/327 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- DAOA | c.210G>T p.L70F | Missense Mutation (SNP) | VAF 91/227 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DBP | c.937G>C p.A313P | Missense Mutation (SNP) | VAF 53/277 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- DCDC1 | c.676C>G p.P226A | Missense Mutation (SNP) | VAF 55/302 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- DCHS1 | c.4453G>T p.A1485S | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DCSTAMP | c.84C>A p.D28E | Missense Mutation (SNP) | VAF 244/620 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.053); called by muse, varscan2
- DCSTAMP | c.266G>T p.C89F | Missense Mutation (SNP) | VAF 232/570 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); called by muse, varscan2
- DCT | c.474C>G p.I158M | Missense Mutation (SNP) | VAF 184/448 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- DDI1 | c.575_576insCA p.L192Ffs*24 | Frame Shift Ins (INS) | VAF 32/210 reads (15%) | called by mutect2, varscan2
- DDX54 | c.874G>T p.G292C | Missense Mutation (SNP) | VAF 67/384 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX60L | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DENND4A | c.3066G>T p.Q1022H | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DENND4A | c.3065A>C p.Q1022P | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DGKB | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGKD | c.2441A>T p.Y814F (on ENST00000264057 / NM_152879.3; = p.Y770F on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/324 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- DISP3 | c.1623C>A p.Y541* | Nonsense Mutation (SNP) | VAF 37/183 reads (20%) | called by muse, mutect2, varscan2
- DLG5 | c.3967T>A p.S1323T | Missense Mutation (SNP) | VAF 55/300 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DLG5 | c.3509C>T p.P1170L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- DMXL1 | c.1778T>G p.F593C | Missense Mutation (SNP) | VAF 94/217 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- DNAH10 | c.5042C>A p.A1681E (on ENST00000409039; = p.A1620E on NM_207437.3) | Missense Mutation (SNP) | VAF 73/554 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- DNAH3 | c.11898C>G p.I3966M | Missense Mutation (SNP) | VAF 56/372 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- DNAH7 | c.9065G>T p.R3022M | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- DNAH7 | c.8419G>T p.A2807S | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- DNAH8 | c.4208C>G p.S1403C | Missense Mutation (SNP) | VAF 41/250 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DOT1L | c.2881G>T p.E961* | Nonsense Mutation (SNP) | VAF 45/238 reads (19%) | called by muse, mutect2, varscan2
- DRD5 | c.1144A>T p.T382S | Missense Mutation (SNP) | VAF 94/277 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- DSG3 | c.2545C>T p.L849F | Missense Mutation (SNP) | VAF 147/412 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DST | c.6053C>A p.A2018D | Missense Mutation (SNP) | VAF 22/368 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- DUOX2 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 36/290 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DZIP1L | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- EAF2 | c.383A>T p.Q128L | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.162); called by muse, mutect2
- ECEL1 | c.2236G>A p.G746S | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ECT2 | c.2245G>T p.D749Y (on ENST00000392692 / NM_001349098.2; = p.D718Y on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- EEF2K | c.1504G>T p.V502L | Missense Mutation (SNP) | VAF 86/303 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- EIF2D | c.1595C>A p.T532N | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- EIF3A | c.1566G>T p.Q522H | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ENDOU | c.434C>G p.S145C (on ENST00000422538 / NM_001172439.2; = p.S104C on NM_006025.4) | Missense Mutation (SNP) | VAF 20/410 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2
- ENPEP | c.200C>A p.P67H | Missense Mutation (SNP) | VAF 75/178 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- EP400 | c.231G>T p.Q77H | Missense Mutation (SNP) | VAF 128/302 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- EPB41L1 | c.1774G>T p.V592L | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPB42 | c.505G>C p.G169R (on ENST00000441366 / NM_001114134.2; = p.G199R on NM_000119.3) | Missense Mutation (SNP) | VAF 88/531 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHX4 | c.139C>A p.P47T | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- EPPK1 | c.4220G>T p.S1407I | Missense Mutation (SNP) | VAF 94/729 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- ERRFI1 | c.163A>T p.S55C | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- ERVFRD-1 | c.859C>A p.H287N | Missense Mutation (SNP) | VAF 51/256 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- ERVV-1 | c.399T>A p.C133* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | called by mutect2, varscan2
- ESPN | c.886G>T p.A296S | Missense Mutation (SNP) | VAF 71/320 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- ESX1 | c.784C>G p.P262A | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2
- ETFB | c.254G>T p.R85L | Missense Mutation (SNP) | VAF 121/560 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- EXD2 | c.776G>T p.G259V (on ENST00000312994 / NM_001193362.1; = p.G134V on NM_018199.3) | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); called by muse, mutect2
- EYS | c.1617C>A p.C539* | Nonsense Mutation (SNP) | VAF 58/298 reads (19%) | called by muse, mutect2, varscan2
- F5 | c.6288G>A p.W2096* | Nonsense Mutation (SNP) | VAF 81/578 reads (14%) | called by muse, mutect2, varscan2
- FAM117B | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); called by muse, mutect2
- FAM135B | c.228C>A p.Y76* | Nonsense Mutation (SNP) | VAF 34/301 reads (11%) | called by muse, mutect2, varscan2
- FAM178B | c.1204G>T p.G402C | Missense Mutation (SNP) | VAF 51/294 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- FAM181B | c.344C>A p.P115Q | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- FAM20B | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 83/254 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FAM227B | c.51+7A>T | Splice Region (SNP) | VAF 40/227 reads (18%) | called by muse, mutect2, varscan2
- FAM78B | c.744G>T p.R248S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FASLG | c.797T>C p.L266P | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT1 | c.13191A>G p.I4397M | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAT3 | c.1462G>T p.G488* | Nonsense Mutation (SNP) | VAF 63/172 reads (37%) | called by muse, mutect2, varscan2
- FAT3 | c.7588C>A p.Q2530K | Missense Mutation (SNP) | VAF 57/408 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- FAT3 | c.7733G>T p.G2578V | Missense Mutation (SNP) | VAF 62/406 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT3 | c.13093C>A p.L4365M | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBN2 | c.2062C>A p.L688M | Missense Mutation (SNP) | VAF 149/385 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- FBN2 | c.1081C>G p.Q361E | Missense Mutation (SNP) | VAF 69/453 reads (15%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- FBRSL1 | c.679G>T p.G227* | Nonsense Mutation (SNP) | VAF 90/280 reads (32%) | called by muse, mutect2, varscan2
- FER1L6 | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 60/411 reads (15%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FER1L6 | c.4838A>G p.E1613G | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- FFAR4 | c.888C>G p.I296M | Missense Mutation (SNP) | VAF 120/442 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FGD2 | c.786G>T p.K262N | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FHL2 | c.354G>T p.K118N | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FLNC | c.2884C>G p.P962A | Missense Mutation (SNP) | VAF 115/584 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FLNC | c.2996T>C p.L999P | Missense Mutation (SNP) | VAF 102/544 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FLT4 | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- FNDC10 | c.202G>T p.G68C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); called by mutect2, varscan2
- FSIP2 | c.263C>A p.P88H | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- FSIP2 | c.6055G>A p.D2019N | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- FSIP2 | c.6335C>G p.S2112* | Nonsense Mutation (SNP) | VAF 93/295 reads (32%) | called by muse, mutect2, varscan2
- FSIP2 | c.12040G>C p.V4014L | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FSIP2 | c.15181C>A p.L5061I | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- FSTL5 | c.1064G>T p.G355V | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FYCO1 | c.3775G>T p.G1259W | Missense Mutation (SNP) | VAF 49/308 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- FZD2 | c.626C>G p.S209C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- GABARAP | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 42/243 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- GABRA2 | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT tolerated, low confidence (0.42); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- GABRG3 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GAD2 | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 53/383 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GAK | c.2320G>T p.E774* | Nonsense Mutation (SNP) | VAF 71/339 reads (21%) | called by muse, mutect2, varscan2
- GALK2 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 50/297 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALK2 | c.1177G>T p.G393W | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNT13 | c.277C>A p.L93I | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- GAPVD1 | c.3463G>T p.D1155Y (on ENST00000394104; = p.D1164Y on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/189 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- GAREM1 | c.1022G>T p.R341L | Missense Mutation (SNP) | VAF 105/348 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GCA | c.27+1del | Frame Shift Del (DEL) | VAF 47/263 reads (18%) | called by mutect2, pindel, varscan2
- GCC1 | c.1225G>C p.A409P | Missense Mutation (SNP) | VAF 74/314 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GCSAML | c.249C>A p.S83R | Missense Mutation (SNP) | VAF 72/428 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- GFM1 | c.1909+8G>T | Splice Region (SNP) | VAF 97/268 reads (36%) | called by muse, mutect2, varscan2
- GINM1 | c.526C>T p.L176F | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLYATL2 | c.275C>A p.S92Y | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- GNAT1 | c.254C>A p.T85N | Missense Mutation (SNP) | VAF 109/593 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGA8J | c.1067G>T p.R356M | Missense Mutation (SNP) | VAF 168/806 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, varscan2
- GPR137C | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 110/401 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- GPR149 | c.122G>T p.C41F | Missense Mutation (SNP) | VAF 78/428 reads (18%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR155 | c.1366A>T p.S456C | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- GPR78 | c.604C>A p.H202N | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPRIN1 | c.1681G>T p.A561S | Missense Mutation (SNP) | VAF 125/303 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPX1 | c.456G>T p.W152C | Missense Mutation (SNP) | VAF 56/329 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRAMD1C | c.1072A>T p.S358C | Missense Mutation (SNP) | VAF 105/315 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- GREB1 | c.2677C>A p.L893M | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIFIN | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 32/473 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.296); called by muse, mutect2
- GRIP2 | c.1657G>T p.E553* (on ENST00000619221; = p.E456* on NM_001080423.4) | Nonsense Mutation (SNP) | VAF 40/208 reads (19%) | called by muse, mutect2, varscan2
- GRK2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 13/326 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.013); called by muse, mutect2
- GRK5 | c.376G>T p.V126F | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2
- GRM4 | c.1183G>T p.G395W | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- GSK3B | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 79/172 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GTF3C2 | c.1366A>T p.R456W | Missense Mutation (SNP) | VAF 73/235 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- GUCY2F | c.1970del p.G657Afs*2 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | called by mutect2, pindel, varscan2
- HAND2 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- HAUS5 | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 58/255 reads (23%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- HCRTR2 | c.118C>A p.L40M | Missense Mutation (SNP) | VAF 246/721 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- HDGF | c.499A>G p.K167E | Missense Mutation (SNP) | VAF 50/453 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HEATR5A | c.193G>T p.G65W | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HECTD1 | c.5309A>C p.Q1770P | Missense Mutation (SNP) | VAF 71/462 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- HELQ | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEPACAM2 | c.200T>C p.I67T (on ENST00000394468 / NM_001039372.4; = p.I55T on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/345 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- HEPH | c.592G>C p.G198R (on ENST00000343002; = p.G252R on NM_138737.5) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HERC2 | c.9277A>G p.I3093V | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- HERC6 | c.547C>A p.L183M | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- HEXA | c.710A>G p.Q237R | Missense Mutation (SNP) | VAF 71/433 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMCN1 | c.90del p.R31Efs*18 | Frame Shift Del (DEL) | VAF 58/454 reads (13%) | called by mutect2, pindel, varscan2
- HMCN1 | c.14765C>A p.A4922E | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- HMGXB3 | c.2189A>C p.K730T (on ENST00000613459; = p.K484T on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.038); called by mutect2, varscan2
- HOXA9 | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- HOXB5 | c.582dup p.K195Efs*143 | Frame Shift Ins (INS) | VAF 58/294 reads (20%) | called by mutect2, pindel
- HOXB6 | c.561G>C p.E187D | Missense Mutation (SNP) | VAF 111/652 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HPS4 | c.1231_1241del p.S411Hfs*4 | Frame Shift Del (DEL) | VAF 93/509 reads (18%) | called by mutect2, pindel, varscan2
- HPS5 | c.2718-1G>A p.X906_splice (on ENST00000349215 / NM_181507.2; = p.X792_splice on NM_007216.4) | Splice Site (SNP) | VAF 62/367 reads (17%) | called by muse, mutect2, varscan2
- HR | c.2380A>T p.T794S | Missense Mutation (SNP) | VAF 75/431 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HS3ST4 | c.667G>T p.V223L | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- HUWE1 | c.11994C>A p.R3998= | Splice Region (SNP) | VAF 22/344 reads (6%) | called by muse, mutect2
- HYDIN | c.10047C>A p.H3349Q | Missense Mutation (SNP) | VAF 56/272 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- IFNLR1 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- IFT43 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 71/402 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGHD | c.682C>A p.Q228K | Missense Mutation (SNP) | VAF 161/699 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- IGHG1 | c.292G>T p.V98F | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- IGHV3-7 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 95/356 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- IGHV5-51 | c.64C>G p.Q22E | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IGKV1-6 | c.327C>G p.Y109* | Nonsense Mutation (SNP) | VAF 105/620 reads (17%) | called by muse, mutect2, varscan2
- IGKV1D-16 | c.325T>A p.Y109N | Missense Mutation (SNP) | VAF 92/579 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- IGLV11-55 | c.136G>T p.D46Y | Missense Mutation (SNP) | VAF 26/253 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- IGLV2-23 | c.118T>A p.S40T | Missense Mutation (SNP) | VAF 256/605 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.174); called by mutect2, varscan2
- IL17RA | c.1528G>T p.D510Y | Missense Mutation (SNP) | VAF 100/463 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- IL1RAPL1 | c.518C>A p.P173Q | Missense Mutation (SNP) | VAF 117/246 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- INO80 | c.2332C>A p.L778I | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- INPP5F | c.955C>A p.H319N | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- IQCA1 | c.2408G>C p.R803P | Missense Mutation (SNP) | VAF 77/409 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IRX4 | c.1253T>A p.L418H | Missense Mutation (SNP) | VAF 99/225 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- ISL1 | c.350G>C p.G117A | Missense Mutation (SNP) | VAF 102/566 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ITGAL | c.1907G>T p.C636F | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITIH2 | c.2264T>A p.L755Q | Missense Mutation (SNP) | VAF 48/235 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ITIH3 | c.1868C>T p.A623V | Missense Mutation (SNP) | VAF 74/337 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ITPK1 | c.791A>T p.E264V | Missense Mutation (SNP) | VAF 71/306 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- JADE2 | c.2116G>T p.G706C | Missense Mutation (SNP) | VAF 99/220 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- JAK2 | c.2627G>T p.G876V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- JAM2 | c.347A>T p.E116V | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- KCNA7 | c.1212G>C p.E404D | Missense Mutation (SNP) | VAF 61/343 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.065); called by muse, mutect2
- KCNH5 | c.2173A>G p.T725A | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNH8 | c.2615G>T p.S872I | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KCNJ16 | c.529A>T p.K177* | Nonsense Mutation (SNP) | VAF 139/467 reads (30%) | called by muse, mutect2, varscan2
- KCNJ3 | c.1186A>G p.T396A | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNMA1 | c.2752A>T p.N918Y (on ENST00000286628 / NM_001161352.2; = p.N860Y on NM_002247.4) | Missense Mutation (SNP) | VAF 145/442 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNMA1 | c.1916dup p.N639Kfs*9 | Frame Shift Ins (INS) | VAF 153/589 reads (26%) | called by mutect2, pindel, varscan2
- KCNQ2 | c.2045G>A p.R682K (on ENST00000359125 / NM_172107.4; = p.R654K on NM_004518.6) | Missense Mutation (SNP) | VAF 122/291 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNT2 | c.3370G>T p.V1124F | Missense Mutation (SNP) | VAF 113/347 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- KCNT2 | c.3073G>T p.G1025C | Missense Mutation (SNP) | VAF 126/390 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- KCNT2 | c.1998G>T p.E666D | Missense Mutation (SNP) | VAF 64/236 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCP | c.2668T>A p.C890S (on ENST00000620378; = p.C950S on NM_001366122.1) | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- KIAA0825 | c.3581T>C p.V1194A | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIAA1549L | c.30G>C p.Q10H (on ENST00000321505; = p.Q307H on NM_012194.3) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.123); called by muse, mutect2
- KIAA1614 | c.2605G>C p.V869L | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- KIAA1671 | c.3340G>T p.A1114S | Missense Mutation (SNP) | VAF 156/483 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KIF1C | c.2446G>T p.G816C | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- KIF20B | c.2245A>T p.I749F (on ENST00000371728 / NM_001284259.2; = p.I709F on NM_016195.4) | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- KIF26B | c.349G>T p.G117C | Missense Mutation (SNP) | VAF 217/600 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- KIF4B | c.1509G>T p.E503D | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIF5A | c.1905+8C>A | Splice Region (SNP) | VAF 172/434 reads (40%) | called by muse, mutect2, varscan2
- KIN | c.824C>G p.A275G | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIR3DL1 | c.215A>T p.H72L | Missense Mutation (SNP) | VAF 54/373 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- KLF8 | c.250G>T p.V84L | Missense Mutation (SNP) | VAF 91/162 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- KLHL1 | c.960C>A p.F320L | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- KLHL32 | c.743A>G p.H248R | Missense Mutation (SNP) | VAF 19/361 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.014); called by muse, mutect2
- KLK15 | c.481+2T>A p.X161_splice | Splice Site (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- KMT2B | c.6134C>T p.P2045L | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- KMT2D | c.15020G>T p.R5007L | Missense Mutation (SNP) | VAF 83/770 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- KRBA1 | c.2122A>T p.R708W | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- KRT15 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 75/405 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- KRT33A | c.783C>A p.S261R | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- KRT72 | c.149C>A p.S50Y | Missense Mutation (SNP) | VAF 350/797 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRTAP27-1 | c.332G>A p.C111Y | Missense Mutation (SNP) | VAF 128/349 reads (37%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- LAMA1 | c.6026C>A p.A2009D | Missense Mutation (SNP) | VAF 74/384 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.108); called by muse, mutect2
1,047 further variants in this file (477 protein-altering or splice-affecting, 336 silent, 234 other) are not listed here.
